Gene-level copy-number profile of tumor specimen TCGA-B5-A1MU-01A from TCGA case TCGA-B5-A1MU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 79.5 years (29,027 days).
Specimen TCGA-B5-A1MU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.a1e05ea6-801a-442d-b6a1-98f2d55198a3.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B5-A1MU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 403 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ba409761-d447-4383-9e9e-8a671548aac0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,630; copy number 1: 17,095; copy number 2: 24,507; copy number 3: 9,298; copy number 4: 2,776; copy number 5: 2,397; copy number 6: 169; copy number 7: 128; copy number 9: 51; copy number 11: 21; copy number 12: 6; copy number 13: 31; copy number 14: 25; copy number 21: 4; copy number 23: 8; copy number 26: 22; copy number 53: 33; copy number 56: 13; copy number 63: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B5-A1MU-01A-11D-A13J-01): tumor purity 0.25, ploidy 2.15, whole-genome doublings 0.

Caution: 3,024 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 3,024 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:149,170,561–149,184,570, 1 gene (within-gene range 0–3): AC009230.1.
- chr3:75,384,059–75,590,649, 11 genes: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1.
- chr5:50,396,192–51,167,647, 14 genes: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P.
- chr5:52,008,031–52,799,956, 4 genes (within-gene range 0–2): LINC02118, RPS17P11, MFSD4BP1, AC022126.1.
- chr5:56,919,602–62,628,582, 75 genes (broad region; genes not listed).
- chr6:391,752–796,781, 9 genes (within-gene range 0–1): IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5.
- chr6:15,246,069–15,522,042, 1 gene (within-gene range 0–4): JARID2.
- chr6:15,314,920–15,935,315, 6 genes: RNU6-522P, RNU6-645P, 5S_rRNA, DTNBP1, AL021978.1, ARPC3P5.
- chr9:60,914,407–138,203,325, 1,541 genes (broad region; genes not listed).
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr12:9,480,608–9,576,275, 2 genes (within-gene range 0–2): AC092821.1, AC092821.2.
- chr15:19,878,555–48,304,078, 880 genes (within-gene range 0–1) (broad region; genes not listed).
- chr17:10,521,148–14,231,736, 58 genes (within-gene range 0–3): MYH2, AC005323.1, MYH3, AC002347.1, SCO1, AC002347.2, ADPRM, TMEM220, MAGOH2P, TMEM220-AS1, AC015908.7, AC015908.3, AC015908.1, AC015908.4, AC015908.6, TMEM238L, AC015908.5, PIRT, AC015908.2, RNU6-1065P, RPL15P21, RN7SL601P, AC005548.1, SHISA6, AC005725.1, DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1, MYOCD, MYOCD-AS1, AC005358.1, ARHGAP44, MIR1269B, AC005274.1, AC005277.2, AC005277.1, ELAC2, AC005303.1, LINC02093, HS3ST3A1, MIR548H3, COX10-AS1, AC005304.2, AC005304.1, AC005304.3, CDRT15P1, COX10, SNORA74.
- chr17:17,674,026–19,579,034, 118 genes (within-gene range 0–2) (broad region; genes not listed).
- chr22:40,673,484–50,801,309, 303 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,632 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,924,740–248,919,946, 2,096 genes, copy number 5 (broad region; genes not listed).
- chr2:88,811,186–88,861,563, 1 gene, copy number 14 (within-gene range 3–14): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 14: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr6:15,994,944–23,404,132, 92 genes, copy number 5–13 (broad region; genes not listed).
- chr8:54,191,582–54,470,609, 8 genes, copy number 9: AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1.
- chr8:56,776,283–57,805,029, 14 genes, copy number 9 (within-gene range 1–9): AC009597.2, RNU6-13P, BPNT2, RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10, AC068075.2, AC090796.1, AC104051.1.
- chr8:65,526,738–67,746,378, 46 genes, copy number 7–23: LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1.
- chr8:85,373,436–88,019,113, 48 genes, copy number 7–26 (within-gene range 2–26): CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1.
- chr8:89,585,872–91,219,236, 26 genes, copy number 7 (within-gene range 2–7): AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP.
- chr8:96,261,902–98,036,724, 21 genes, copy number 5–6 (within-gene range 2–6): PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2, CPQ, AP003117.2, AP003117.1, AP003115.1, TSPYL5, SNORD3H, AP002982.1, AP002982.2, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2.
- chr8:126,556,323–127,419,050, 1 gene, copy number 56 (within-gene range 2–56): PCAT1.
- chr8:126,671,522–130,443,674, 51 genes, copy number 53–63 (within-gene range 1–63): RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1.
- chr11:114,391,443–120,988,906, 192 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).
- chr17:22,221,221–22,524,663, 12 genes, copy number 6: FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1.

Autosomal genes at a single copy (total copy number 1): 16,760. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
